Gene-level copy-number profile of tumor specimen TCGA-91-7771-01A from TCGA case TCGA-91-7771, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.8 years (22,926 days).
Specimen TCGA-91-7771-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.2925e8ba-d1cd-421c-a906-c638e5528478.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-91-7771-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5d016e32-dfcb-473b-92cd-db23afeb13df

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 302; copy number 2: 1,920; copy number 3: 12,722; copy number 4: 15,019; copy number 5: 16,931; copy number 6: 8,107; copy number 7: 1,286; copy number 8: 1,206; copy number 9: 809; copy number 10: 289; copy number 11: 59; copy number 12: 362; copy number 13: 231; copy number 14: 26; copy number 15: 79; copy number 16: 30; copy number 17: 4; copy number 18: 247; copy number 19: 96; copy number 20: 7; copy number 22: 1; copy number 24: 52; copy number 26: 1; copy number 29: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-91-7771-01A-11D-2166-01): tumor purity 0.32, ploidy 5, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 1,218 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:15,778,275–16,512,187, 14 genes, copy number 14: CD38, HPRT1P1, FGFBP1, FGFBP2, PROM1, AC108063.2, TAPT1, AC108063.1, TAPT1-AS1, RPS21P4, AC006427.1, AC006427.2, ZEB2P1, AC097515.1.
- chr4:17,427,696–17,634,105, 8 genes, copy number 13: RPS7P6, QDPR, CLRN2, NACAP5, AC006160.2, LAP3, AC006160.1, MED28.
- chr4:18,418,662–19,098,740, 3 genes, copy number 20: AC093898.1, AC093871.1, AC006840.1.
- chr4:19,181,814–19,181,856, 1 gene, copy number 20: RNA5SP157.
- chr4:20,251,905–21,948,772, 13 genes, copy number 13: SLIT2, SLIT2-IT1, MIR218-1, PACRGL, KCNIP4, AC097505.1, AC110296.1, MIR7978, AC096576.7, AC096576.3, AC096576.1, AC096576.2, KCNIP4-IT1.
- chr4:22,989,147–27,025,381, 49 genes, copy number 12 (within-gene range 9–12): AC097512.1, AC092440.1, RFPL4AP3, AC093607.1, ERVH-1, PPARGC1A, AC092834.1, DHX15, MIR573, RN7SL16P, ATP5MGP3, LINC02473, AC006390.1, HNRNPA1P65, SOD3, CCDC149, LGI2, SEPSECS, SEPSECS-AS1, PI4K2B, AC104662.1, U2, ZCCHC4, ANAPC4, AC133963.2, AC133963.1, AC105290.1, RNU7-126P, AC092436.1, SLC34A2, RPS29P11, AC092436.2, MTND4P9, MTND4LP22, MTND3P5, MTCO3P44, SEL1L3, AC092436.3, SMIM20, AC133961.1, LINC02357, AC097714.1, RBPJ, CCKAR, TBC1D19, AC107390.1, STIM2, STIM2-AS1, PIMREGP4.
- chr4:30,720,415–31,146,805, 3 genes, copy number 20 (within-gene range 5–20): PCDH7, AC097716.1, MTCYBP43.
- chr4:33,010,948–33,238,670, 3 genes, copy number 11: MAPRE1P2, AC093606.1, AC093878.1.
- chr8:150,584–7,039,439, 109 genes, copy number 11–26 (broad region; genes not listed).
- chr8:63,384,839–66,197,315, 38 genes, copy number 18–24: AC011124.1, IFITM8P, AC011124.2, AC018953.1, RN7SKP135, AC018953.2, LINC01414, AC069133.1, LINC01289, COX6CP8, MIR124-2HG, MIR124-2, AC012535.1, AC090136.1, AC090136.2, AC090136.3, BHLHE22, CYP7B1, AC104232.2, AC104232.3, AC104232.1, AC087808.1, RPL31P41, LINC00251, PPIAP86, LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967.
- chr8:70,669,339–71,702,786, 7 genes, copy number 11 (within-gene range 3–11): XKR9, AC015687.1, Y_RNA, AC022858.1, EYA1, TRAPPC2P2, AC009446.1.
- chr8:73,297,711–84,921,844, 158 genes, copy number 13–29 (within-gene range 6–29) (broad region; genes not listed).
- chr8:85,833,377–87,615,219, 24 genes, copy number 13 (within-gene range 8–13): AC100801.1, LINC02849, AC100801.2, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1, SLC7A13, AC103760.1, WWP1, RMDN1, NTAN1P2, SLC2A3P4, CPNE3, CNGB3, MIOXP1, GOLGA2P1, UBE2Q2P10, AC090572.3, AC090572.2, AC090572.1, CNBD1.
- chr8:95,947,781–96,611,790, 14 genes, copy number 13: SRSF3P2, AC012339.1, GAPDHP30, AC007992.1, AP003465.2, GDF6, UQCRB, AP003465.1, MTERF3, PTDSS1, Y_RNA, AP003548.1, RNU6-1172P, SDC2.
- chr8:123,497,889–145,066,685, 405 genes, copy number 12–24 (broad region; genes not listed).
- chr12:67,989,445–68,234,686, 1 gene, copy number 19 (within-gene range 7–19): IFNG-AS1.
- chr12:68,035,767–71,667,725, 77 genes, copy number 15–19 (within-gene range 3–19) (broad region; genes not listed).
- chr12:72,087,266–75,044,793, 25 genes, copy number 16 (within-gene range 3–16): TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1, AC090503.2, LINC02444, AC090503.1, AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1, AC123904.2, AC123904.1, AC123904.3, AC073525.1.
- chr12:79,341,205–79,559,166, 5 genes, copy number 15 (within-gene range 3–15): AC027288.3, MIR1252, AC027288.2, AC027288.1, NOP56P3.
- chr12:84,147,304–84,449,878, 4 genes, copy number 17: AC090679.3, AC090679.2, AC090679.1, AC087888.1.
- chr14:37,595,847–38,041,442, 1 gene, copy number 11 (within-gene range 7–11): TTC6.
- chr14:37,827,798–40,390,547, 32 genes, copy number 11 (within-gene range 8–11): RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A, AL355835.1, AL357094.1, KRT8P1, LINC00639, AL132994.1, AL132994.2, Y_RNA, SEC23A, AL109628.1, SEC23A-AS1, PPIAP4, GEMIN2, TRAPPC6B, AL109628.2, RPL7AP2, AL132639.3, PNN, AL132639.1, YTHDF2P1, MIA2, AL132639.2, GLRX5P3, COILP1, FBXO33, AL049828.1.
- chr14:42,259,731–45,200,890, 37 genes, copy number 13: AL445074.1, AL442163.1, AL450442.1, AL442163.2, AL442163.3, YWHAQP1, AL163153.1, TUBBP3, HNRNPUP1, AL583809.1, KRT8P2, AL358913.1, ARHGAP16P, LINC02307, EIF4BP1, AL109766.1, YWHAZP1, AL161752.1, LINC02277, FSCB, AL356022.1, LINC02302, DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3, KLHL28, TOGARAM1, AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3, FANCM.
- chr14:56,117,316–60,180,016, 75 genes, copy number 12 (broad region; genes not listed).
- chr15:61,834,682–62,060,473, 2 genes, copy number 15 (within-gene range 10–15): AC009554.1, VPS13C.
- chr15:62,060,503–64,868,002, 70 genes, copy number 15 (broad region; genes not listed).
- chr15:66,278,498–67,807,117, 40 genes, copy number 13–18 (within-gene range 7–18): AC055855.2, DIS3L, AC055855.1, TIPIN, SCARNA14, Y_RNA, RPL9P25, MAP2K1, ATP5MFP6, RPL35AP32, AC116913.1, SNAPC5, MIR4512, RPL4, SNORD18C, AC116913.2, SNORD18B, SNORD16, SNORD18A, ZWILCH, LCTL, LINC01169, SMAD6, AC013564.1, AC110048.1, AC110048.2, AC093334.1, LINC02206, AC087482.1, HMGN2P47, SMAD3, AC012568.1, AAGAB, RPS24P16, IQCH, IQCH-AS1, C15orf61, AC016355.1, MAP2K5, HNRNPA1P5.

Autosomal genes at a single copy (total copy number 1): 302. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
